Somatic mutation profile of tumor specimen TARGET-10-PARCHU-09A (aliquot TARGET-10-PARCHU-09A-01D) from TARGET case TARGET-10-PARCHU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (941 days).
Specimen TARGET-10-PARCHU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f97bcb39-078f-4633-ab66-3ebb9e68c98f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCHU-10A (Blood Derived Normal), aliquot TARGET-10-PARCHU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1ca5568-f13c-4ce1-b7da-aaf41f3dee71

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EPS8L2 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs754877967, COSV59346718; called by mutect2, varscan2
- PLXNA1 | c.3974G>A p.R1325Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs910229522; called by muse, mutect2, varscan2
- ADAM12 | c.2304C>T p.L768= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs1018648383, COSV100900780; called by muse, mutect2, varscan2
- MIR4477B | n.31A>C | RNA (SNP) | VAF 6/43 reads (14%) | catalogued as rs75019967; called by muse, varscan2
- OPRM1 | c.1165-10726_1165-10721del | Intron (DEL) | VAF 3/31 reads (10%) | catalogued as rs1307592896; called by mutect2, pindel
